TCGA case TCGA-CA-5255 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/563d67a1-f1ba-4722-aa2d-9b35b1689468

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 45.8 years (16,743 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 376 days (1.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 49 days; Treatment dose: 5,000 cGy; Course number: 1; Number of fractions: 15; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 164 days; Days to treatment end: 331 days; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 2 days; Disease response: Tumor Free.
- Days to follow up: 93 days; Disease response: Tumor Free.
- Days to follow up: 376 days (1.0 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 56 kg; Height: 172 cm; BMI: 18.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CA-5255-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-CA-5255-01A-01-TS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60.
  Slide TCGA-CA-5255-01A-01-BS1: Section location: Bottom; Percent tumor cells: 53; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 3; Percent stromal cells: 30.
- Sample TCGA-CA-5255-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CA-5255-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: No.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Drug treatment 3: Pharmaceutical therapy drug name: Folinic Acid.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 376 days; disease-specific survival: no event (censored), 376 days; disease-free interval: no event (censored), 376 days; progression-free interval: no event (censored), 376 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CA-5255-01A-11D-1834-01): tumor purity 0.27, ploidy 3.18, whole-genome doublings 1.
